Surgical pathology report (de-identified scan), TCGA case TCGA-D5-5538, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-5538-01A (Primary Tumor).

Department of Cancer Pathology (cito)

Date

Examination: Histopathological examination

Multiple organ resection – segment of the large intestine

TCGA – D5 – 5538

Material collected on:

Material received on:

Clinical diagnosis: Cancer of the cecum.

Examination performed on

Macroscopic description:

25.3 cm length of the large intestine with periintestinal fat tissue sized 24 x 9 x 2 cm, with a 5 cm length of the small intestine, and a 5.5 cm appendix. Ulcerous tumour sized 4.2 x 4.1 x 0.6 cm found in the mucosa. The lesion surrounding 100% of the intestine circumference, 5 cm from the proximal cut end, 17 cm from the distal cut end, and 1.2 cm from the ileocecal valve. Blue dye injected.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa valvulae Bauhini et parietis ilei et telae adiposae pericolicae. Incision lines free of neoplastic lesions. Metastases carcinomatosa in lymphonodis (No III/VI). Infiltratio carcinomatosa telae adiposae perinodalis. Other lesions of the tumour resident type.

Histopathological diagnosis:

(including examination No.)

Adenocarcinoma tubulopapillare coli. Metastases carcinomatosa in lymphonodis (No III/VI). (G2, Dukes C, Astler-Collier C2, pT3, pN1).

TUBULOPAPILLARY ADENOCARCINOMA OF THE COLON.
METASTATIC LYMPH NODES (III/VI)

Source: NCI Genomic Data Commons file b5676c96-49d5-4329-8bc2-3284fc033592 (TCGA-D5-5538.A376C83C-0084-4006-9371-81088A09DB6B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).